Gene-level copy-number profile of tumor specimen MP2PRT-PAUHKL-TMP1-A from MP2PRT case MP2PRT-PAUHKL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,839 days).
Specimen MP2PRT-PAUHKL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 56379576-81bf-4057-80c5-8638e975e334.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUHKL-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,879 have no estimate.
https://portal.gdc.cancer.gov/files/ed623591-41fa-4381-ab82-5220b012d606

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 287; copy number 1: 6,634; copy number 2: 48,917; copy number 3: 2,906.

Homozygous deletions (total copy number 0; autosomes only): 287 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,257,879–38,265,678, 1 gene (within-gene range 0–1): TRGC1.
- chr7:38,291,616–38,329,643, 7 genes (within-gene range 0–1): TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2.
- chr7:56,940,341–57,020,273, 4 genes: AC069152.1, MIR4283-1, TNRC18P3, SLC29A4P1.
- chr9:20,331,446–22,029,594, 58 genes (within-gene range 0–1): AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B, HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–21,996,013, 1 gene (within-gene range 0–1): AL449423.1.
- chr14:22,147,995–22,552,156, 88 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:105,672,308–106,481,706, 126 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,778. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
